TCGA case TCGA-AO-A12G — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Epithelial Neoplasms, NOS; Primary site: Breast; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/58c56d4b-3f85-4aad-a779-5f9e1791677d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 75 years; Vital status: Alive.

Diagnoses (1)
1. Pleomorphic carcinoma: ICD-O-3 morphology code: 8022/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 75.9 years (27,705 days); Year of diagnosis: 2006; Method of diagnosis: Core Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0 (i+); AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Upper Outer / Breast, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 4; Micrometastasis present: Yes.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Anastrozole; Treatment intent type: Adjuvant; Days to treatment start: 177 days; Treatment outcome: Treatment Ongoing; Prescribed dose: 1; Prescribed dose units: mg/day; Route of administration: Oral.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,266 days (3.5 years); Disease response: Tumor Free.
- Days to follow up: 1,639 days (4.5 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (FISH): 1; Cell count: 23; Specialized molecular test: Signal ratio.
- ERBB2 (FISH): Copy Number Reported; Copy number: 66; Cell count: 23.
- ERBB2 (IHC): Positive; Staining intensity value: 2+.
- ERBB2 amplification (FISH): Negative.
- ESR1 (IHC): Positive; Staining intensity value: 4+; Test value range: 90-99%.
- PGR (IHC): Positive; Staining intensity value: 2+; Test value range: 30-39%.
- Test (FISH): Copy Number Reported; Copy number: 67; Cell count: 23.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AO-A12G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 280 mg.
  Slide TCGA-AO-A12G-01A-01-BSA: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 2; Percent necrosis: 1; Percent stromal cells: 17; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
  Slide TCGA-AO-A12G-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-AO-A12G-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AO-A12G-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Her2 cent17 ratio: 1.0; Axillary staging method: Sentinel node biopsy alone; Surgical procedure first: Simple Mastectomy; Histologic diagnosis: pleomorphic infiltrating lobular carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Micromet detection by IHC: Yes; Er IHC score: 4+; Her2 IHC score: 2+; Method initial path diagnosis: Core needle biopsy; Lymph nodes examined IHC count: 1; Her2 fish method: >=2.0 Positive; Prospective collection: No; Retrospective collection: Yes.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Outer Quadrant; Anatomic organ subdivision: Right.
- Follow-up form 2: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment: Regimen number: 1; Pharmaceutical therapy drug name: Arimidex (Anastrozole).
- Drug treatment, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,639 days; disease-specific survival: no event (censored), 1,639 days; disease-free interval: no event (censored), 1,639 days; progression-free interval: no event (censored), 1,639 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AO-A12G-01A-11D-A10L-01): tumor purity 0.68, ploidy 2.06, whole-genome doublings 0.
